Somatic mutation profile of tumor specimen MMRF_2723_1_BM_CD138pos (aliquot MMRF_2723_1_BM_CD138pos_T1_KHS5U_L14827) from MMRF case MMRF_2723, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.0 years (19,004 days).
Specimen MMRF_2723_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ea5b5d7-d455-44e5-96c0-a787b2eafa18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2723_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2723_1_PB_WBC_C2_KHS5U_L14828; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6dd6d90-29e3-45cd-9fb1-f9fa6aaafce6

The open-access MAF lists 68 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 21, Missense Mutation 17, Intron 9, Silent 8, 5'UTR 3, Nonsense Mutation 2, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 64/154 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CELF6 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1232322825, COSV54717425; called by muse, mutect2, varscan2
- CNTN6 | c.2791A>G p.N931D | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV63185121; called by muse, mutect2, varscan2
- KLK10 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs762681073, COSV59397818; called by muse, mutect2, varscan2
- MCM2 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757173924; called by muse, mutect2, varscan2
- NOTCH3 | c.4996C>T p.R1666W | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1379085406, COSV54650715; called by muse, mutect2, varscan2
- TAF1L | c.4126C>T p.R1376* | Nonsense Mutation (SNP) | VAF 32/160 reads (20%) | catalogued as rs781629508, COSV99644412; called by muse, mutect2, varscan2
- ZNF831 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV64042138; called by muse, mutect2
- AQR | c.4200del p.E1401Kfs*11 | Frame Shift Del (DEL) | VAF 90/421 reads (21%) | called by mutect2, pindel, varscan2
- COL7A1 | c.8171dup p.G2725Rfs*20 | Frame Shift Ins (INS) | VAF 30/92 reads (33%) | called by mutect2, pindel, varscan2
- DNAH14 | c.9035T>C p.V3012A | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- GSTCD | c.1489C>T p.Q497* (on ENST00000360505 / NM_001031720.3; = p.Q410* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- INO80D | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- JUN | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MSI2 | c.425T>A p.M142K | Missense Mutation (SNP) | VAF 128/264 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PDS5B | c.2482G>C p.A828P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, varscan2
- RYR2 | c.11052A>C p.E3684D | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC29A1 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLFN14 | c.728T>A p.V243D | Missense Mutation (SNP) | VAF 185/426 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, varscan2
- TMPRSS7 | c.1958T>G p.L653R (on ENST00000452346; = p.L527R on NM_001042575.2) | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM39 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- UMODL1 | c.329del p.Q110Rfs*68 | Frame Shift Del (DEL) | VAF 64/223 reads (29%) | called by mutect2, pindel, varscan2
- ZNF43 | c.229+2T>G p.X77_splice | Splice Site (SNP) | VAF 76/352 reads (22%) | called by muse, mutect2, varscan2
- ABCG5 | c.444G>A p.L148= | Silent (SNP) | VAF 43/80 reads (54%) | called by muse, mutect2, varscan2
- AL031777.2 | c.123C>G p.S41= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- FBXO38 | c.3051G>A p.K1017= (on ENST00000340253 / NM_205836.3; = p.K942= on NM_030793.5) | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as rs1422351313; called by muse, mutect2, varscan2
- ITGA8 | c.2919C>T p.S973= | Silent (SNP) | VAF 89/219 reads (41%) | called by muse, mutect2, varscan2
- OR4K17 | c.126C>T p.N42= | Silent (SNP) | VAF 107/267 reads (40%) | catalogued as rs558231474, COSV59647819; called by muse, mutect2, varscan2
- RAB29 | c.78A>G p.R26= | Silent (SNP) | VAF 91/232 reads (39%) | called by muse, mutect2, varscan2
- RIMS1 | c.321C>T p.G107= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs1408660383, COSV53462605; called by muse, mutect2, varscan2
- TRPM7 | c.3258C>T p.I1086= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV57917345; called by muse, mutect2, varscan2
- ABHD2 | c.*1318del | 3'UTR (DEL) | VAF 62/170 reads (36%) | called by mutect2, pindel, varscan2
- C5orf64 | n.513-42621A>C | Intron (SNP) | VAF 58/199 reads (29%) | called by muse, mutect2, varscan2
- CDH9 | c.*490T>G | 3'UTR (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- CDK14 | c.-81C>T | 5'UTR (SNP) | VAF 14/47 reads (30%) | catalogued as rs1360566899; called by muse, mutect2, varscan2
- CPEB4 | c.*5179C>T | 3'UTR (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1658G>A | 3'UTR (SNP) | VAF 40/86 reads (47%) | called by muse, mutect2, varscan2
- DCC | c.*5238T>A | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- FOXC1 | c.*456C>T | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- FZD8 | c.*254G>A | 3'UTR (SNP) | VAF 27/53 reads (51%) | catalogued as rs111703785, COSV101020187; called by muse, mutect2, varscan2
- H2AZ2 | chr7:44828486 A>G | 3'Flank (SNP) | VAF 60/118 reads (51%) | called by muse, mutect2, varscan2
- HLA-B | c.344-85T>C | Intron (SNP) | VAF 76/150 reads (51%) | called by muse, mutect2, varscan2
- KCNT2 | c.*2120G>T | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- LTB | c.163-40C>T | Intron (SNP) | VAF 130/347 reads (37%) | catalogued as rs115773593; called by muse, mutect2, varscan2
- MIR4302 | n.12del | RNA (DEL) | VAF 46/128 reads (36%) | called by mutect2, pindel, varscan2
- OR9Q1 | c.-15+53657G>C | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.*2871G>C | 3'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- SFTA3 | n.1107G>A | RNA (SNP) | VAF 72/150 reads (48%) | called by muse, mutect2, varscan2
- SH2D1A | c.*1192A>C | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- SLC25A36 | c.385+2303C>T | Intron (SNP) | VAF 39/136 reads (29%) | called by muse, mutect2, varscan2
- SRPK2 | c.*1059C>T | 3'UTR (SNP) | VAF 92/149 reads (62%) | catalogued as rs547098568; called by muse, mutect2, varscan2
- SSBP2 | c.*2832T>G | 3'UTR (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*582T>A | 3'UTR (SNP) | VAF 45/88 reads (51%) | called by muse, mutect2, varscan2
- STEAP4 | c.*5079T>A | 3'UTR (SNP) | VAF 37/106 reads (35%) | catalogued as rs950920696; called by muse, mutect2, varscan2
- SYNE2 | c.19993-35A>G | Intron (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*1069T>A | 3'UTR (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2, varscan2
- TDRD3 | c.1839+70A>T | Intron (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- TGFBR3 | c.-113-88G>A | Intron (SNP) | VAF 21/43 reads (49%) | catalogued as rs565824545; called by muse, varscan2
- TMEM132B | c.*253C>T | 3'UTR (SNP) | VAF 45/94 reads (48%) | catalogued as rs1302193111; called by muse, mutect2, varscan2
- TMEM235 | c.*780C>T | 3'UTR (SNP) | VAF 66/119 reads (55%) | catalogued as rs368312826; called by muse, mutect2, varscan2
- TOB2 | c.*2516G>C | 3'UTR (SNP) | VAF 77/168 reads (46%) | called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222315 C>T | 5'Flank (SNP) | VAF 34/66 reads (52%) | catalogued as rs570268669; called by muse, mutect2, varscan2
- TRMT10A | c.*1424G>C | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2
- TUBGCP6 | c.-200G>A | 5'UTR (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TVP23C-CDRT4 | c.*1607C>G | 3'UTR (SNP) | VAF 57/144 reads (40%) | called by muse, mutect2, varscan2
- UPB1 | c.364+936del | Intron (DEL) | VAF 40/139 reads (29%) | called by pindel, varscan2
- XKR4 | c.-112G>A | 5'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- ZC3H15 | c.*237A>T | 3'UTR (SNP) | VAF 170/364 reads (47%) | called by muse, mutect2, varscan2
